CPTAC case C204057 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/8be67ab2-0c8e-4f3f-bba8-9844af848e0b

Demographics
Sex at birth: female; Age at index: 65 years; Vital status: Dead; Days to death: 351 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Parietal lobe; Site of resection or biopsy: Parietal lobe; Tumor grade: G4; Residual disease: R2; Last known disease status: With tumor; Days to last known disease status: 351 days; Progression or recurrence: yes; Days to recurrence: 266 days; Tumor focality: Unifocal.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Pack years smoked: 0; Cigarettes per day: 0; Alcohol history: Yes.

Biospecimens (11 samples)
- Samples 1104764, 1104774, 1105227, 1105237, SM-JU34B (5 with the same recorded description): Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
- Samples 1104767, 1105230, SM-JU33Y (3 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 1105284: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
- Sample C204057-TP: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Right; Preservation method: Snap Frozen.
- Sample C204057-TR1: Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Biospecimen anatomic site: Occipital Cortex; Biospecimen laterality: Right; Preservation method: Snap Frozen.
